Gene-level copy-number profile of tumor specimen TCGA-12-0769-01A from TCGA case TCGA-12-0769, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.5 years (19,171 days).
Specimen TCGA-12-0769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.038d04c2-0f72-403f-af2a-d27d8d75957a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56610985-c646-4f17-8d2d-49b5b302a882

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,458; copy number 2: 46,970; copy number 3: 6,094; copy number 13: 78; copy number 15: 79; copy number 19: 126; copy number 22: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-12-0769-01): tumor purity 0.89, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 298 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,895,761–15,118,043, 126 genes, copy number 19 (within-gene range 2–19) (broad region; genes not listed).
- chr7:54,542,325–55,260,256, 15 genes, copy number 22: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr13:102,589,372–113,641,473, 157 genes, copy number 13–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,071. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
